FM case AD14790 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/e1e307df-b1c3-412d-907e-76c4f8845a24

Male, 72.3 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the esophagus; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 25% (pathologist estimate recorded by GDC). Sample type: Metastatic.
